Somatic mutation profile of tumor specimen TCGA-AN-A0FF-01A (aliquot TCGA-AN-A0FF-01A-11W-A050-09) from TCGA case TCGA-AN-A0FF, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 32.7 years (11,929 days).
Specimen TCGA-AN-A0FF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4a6c24e-3b83-4808-a9fd-3963d37a66dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0FF-10A (Blood Derived Normal), aliquot TCGA-AN-A0FF-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dba356ac-c2e2-49b5-bc18-ebe29459f0fb

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 3, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 50/115 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP8L | c.1625A>G p.Y542C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54103943; called by muse, mutect2, varscan2
- ARHGAP32 | c.2105G>A p.R702H (on ENST00000310343 / NM_001378025.1; = p.R353H on NM_014715.4) | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs149060649; called by muse, mutect2, varscan2
- CYP24A1 | c.1247T>C p.M416T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV53775999; called by muse, mutect2, varscan2
- DNAH2 | c.2921T>C p.I974T | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.245); catalogued as COSV66723763; called by muse, mutect2, varscan2
- DRAXIN | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as rs777115169, COSV53844644; called by muse, mutect2, varscan2
- MED14 | c.4336C>T p.L1446F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV59948055; called by muse, mutect2, varscan2
- MEGF8 | c.4009A>G p.T1337A (on ENST00000251268 / NM_001271938.2; = p.T1270A on NM_001410.3) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.554); catalogued as COSV52096140; called by muse, mutect2, varscan2
- MROH2B | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV101270899, COSV68187646; called by muse, mutect2, varscan2
- NR1I3 | c.913C>T p.R305* (on ENST00000367982 / NM_001077480.3; = p.R301* on NM_005122.5) | Nonsense Mutation (SNP) | VAF 46/322 reads (14%) | catalogued as rs769594436, COSV63468871; called by muse, mutect2, varscan2
- OR8H1 | c.73A>T p.M25L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57295342; called by muse, mutect2, varscan2
- PDCD11 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs772009790, COSV63934815; called by muse, mutect2, varscan2
- REV3L | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100725531; called by muse, mutect2
- SNAPC3 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV66402916; called by muse, mutect2, varscan2
- ZNF234 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as rs764285863, COSV70603936; called by muse, mutect2, varscan2
- GNAS | c.178dup p.M60Nfs*7 | Frame Shift Ins (INS) | VAF 43/213 reads (20%) | called by mutect2, pindel, varscan2
- GOLGA3 | c.1046_1058delinsC p.E349_D353delinsA | In Frame Del (DEL) | VAF 19/39 reads (49%) | called by pindel, varscan2*
- PRUNE2 | c.3560G>A p.W1187* | Nonsense Mutation (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- PRPF18 | c.150G>A p.Q50= | Silent (SNP) | VAF 64/180 reads (36%) | catalogued as COSV60725967; called by muse, mutect2, varscan2
- SPEG | c.3447C>T p.A1149= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV56676671; called by muse, mutect2, varscan2
- TTN | c.32019G>A p.E10673= (on ENST00000591111; = p.E9746= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/317 reads (14%) | catalogued as COSV60243732; called by muse, mutect2, varscan2
- YLPM1 | c.924G>A p.R308= | Silent (SNP) | VAF 19/398 reads (5%) | catalogued as COSV99460852; called by muse, mutect2
